FM case AD8347 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/43cbc4f6-685a-447c-ad1c-38181d1748a1

Male, 38.2 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the head, face or neck; specimen biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
